Somatic mutation profile of tumor specimen TCGA-YL-A8HL-01A (aliquot TCGA-YL-A8HL-01A-11D-A364-08) from TCGA case TCGA-YL-A8HL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.2 years (21,249 days).
Specimen TCGA-YL-A8HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcc5dd70-5069-4ad9-8b31-a8547c6c7fa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8HL-10A (Blood Derived Normal), aliquot TCGA-YL-A8HL-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3e7029d-d931-4630-8eca-c36b5dd821ae

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALT5 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100866998, COSV99056813; called by muse, mutect2, varscan2
- BCAR3 | c.2168C>T p.T723I | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV99550695; called by muse, mutect2, varscan2
- CDH18 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs756583982, COSV56898623; called by muse, mutect2, varscan2
- CDH20 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as rs1160113503, COSV99405253; called by muse, mutect2, varscan2
- CEP57 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100334671; called by muse, mutect2, varscan2
- CNGB1 | c.3379G>A p.G1127S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs373477921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT3 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99431549; called by muse, mutect2, varscan2
- GPRASP2 | c.1818C>A p.D606E | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as rs753150242, COSV100176712; called by muse, mutect2, varscan2
- INSIG1 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100452973; called by muse, mutect2
- ITGAE | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.81); PolyPhen benign (0.153); catalogued as rs147766404; called by muse, mutect2, varscan2
- NOX3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs527483156, COSV50157240; called by muse, mutect2, varscan2
- OR7D2 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100713005; called by muse, mutect2
- SCN4A | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101438460; called by muse, mutect2, varscan2
- SLCO1B1 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs748860610, COSV57007405; called by muse, mutect2, varscan2
- TP53 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM951232, COSV52837901, COSV52987484, COSV53189701, COSV53518652; called by muse, mutect2, varscan2
- ZNF215 | c.1093A>C p.T365P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.36); catalogued as COSV99549548; called by muse, mutect2, varscan2
- ITPR2 | c.3048C>T p.D1016= | Silent (SNP) | VAF 89/209 reads (43%) | catalogued as COSV101189966; called by muse, mutect2, varscan2
- REN | c.666C>T p.D222= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs773236366, COSV99689510; called by muse, mutect2, varscan2
- SALL1 | c.480C>T p.G160= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs777818027, COSV99173598; called by muse, mutect2, varscan2
- ARMC5 | c.1864+272G>T | Intron (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99192498; called by muse, mutect2, varscan2
- RGS3 | c.3081-261G>T | Intron (SNP) | VAF 21/65 reads (32%) | catalogued as rs1349532848, COSV100636709; called by muse, mutect2, varscan2
